Gene-level copy-number profile of tumor specimen HCM-CSHL-0860-C18-06A from HCMI case HCM-CSHL-0860-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 70.3 years (25,687 days).
Specimen HCM-CSHL-0860-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9c180de3-d02f-4be1-8913-aea9fb3e7de6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0860-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/cdd16745-40ef-42dc-86b7-9e9d5f75bdf4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 10,211; copy number 2: 37,505; copy number 3: 10,255; copy number 4: 750; copy number 5: 139; copy number 6: 5.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,691,262–49,691,523, 1 gene (within-gene range 0–2): AL390023.1.
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr4:61,775,449–61,775,850, 1 gene (within-gene range 0–1): AC108161.1.
- chr4:66,003,281–66,016,792, 1 gene (within-gene range 0–1): AC096721.1.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:91,319,034–91,325,306, 1 gene (within-gene range 0–1): AC074124.1.
- chr14:23,969,874–24,051,377, 2 genes (within-gene range 0–1): DHRS4L2, AL136419.1.
- chr16:6,380,476–6,395,578, 1 gene (within-gene range 0–1): AC006112.1.
- chr16:6,703,883–7,614,992, 9 genes (within-gene range 0–2): AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–1): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–3): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 144 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:61,077,224–64,327,972, 144 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,690. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
